Somatic mutation profile of tumor specimen MP2PRT-PARWFA-TMP1-A (aliquot MP2PRT-PARWFA-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARWFA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 4.7 years (1,706 days).
Specimen MP2PRT-PARWFA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffa5f0b9-b1a1-4870-9cca-729bdc4cf6ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWFA-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWFA-NB1-B-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53dddc68-44fe-483f-b8c2-3abfbd9f4f53

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSJ | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 110/263 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs367878518; called by muse, mutect2, varscan2
- BACH2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV57584048, COSV99998937; called by muse, mutect2
- CCNL2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs369004818; called by muse, mutect2, varscan2
- DCLRE1A | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 113/265 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV63748203; called by muse, mutect2, varscan2
- HTR1A | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 220/459 reads (48%) | catalogued as COSV60500791; called by muse, mutect2, varscan2
- INF2 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 111/225 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs775431460, COSV53033962; called by muse, mutect2, varscan2
- MRPL20 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV61224174, COSV61224279; called by muse, mutect2, varscan2
- SECISBP2L | c.1388C>T p.S463L (on ENST00000559471 / NM_001193489.2; = p.S418L on NM_014701.4) | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99961078; called by muse, mutect2, varscan2
- TRIM2 | c.1405G>A p.E469K (on ENST00000437508; = p.E496K on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV58630789; called by muse, mutect2, varscan2
- TRIM42 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 13/412 reads (3%) | catalogued as COSV53882347; called by muse, mutect2
- VTI1A | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101261390; called by muse, mutect2
- CCDC168 | c.9034C>G p.Q3012E | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CCNL2 | c.812A>T p.E271V | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP54 | c.2444C>G p.S815C | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2
- CLIC6 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 237/738 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- EPHX2 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- GLYATL1 | c.120C>G p.F40L (on ENST00000317391 / NM_001354699.1; = p.F71L on NM_080661.4) | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- KIAA1217 | c.3964C>G p.H1322D | Missense Mutation (SNP) | VAF 129/244 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NPEPPS | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- PRR36 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- RAPGEF1 | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- STRA8 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.107); called by muse, mutect2
- TOM1L1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TULP4 | c.3421C>G p.Q1141E | Missense Mutation (SNP) | VAF 186/394 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WLS | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.294); called by muse, mutect2
- CABP1 | c.540C>T p.G180= | Silent (SNP) | VAF 258/506 reads (51%) | called by muse, mutect2, varscan2
- FOXG1 | c.51G>A p.S17= | Silent (SNP) | VAF 153/330 reads (46%) | called by muse, mutect2, varscan2
- JADE2 | c.651C>T p.V217= | Silent (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- OR1S2 | c.414G>A p.A138= | Silent (SNP) | VAF 152/327 reads (46%) | catalogued as rs145253819; called by muse, mutect2, varscan2
- PGR | c.1926C>T p.F642= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as rs374105960; called by muse, mutect2
- RNF213 | c.6438G>C p.L2146= | Silent (SNP) | VAF 98/234 reads (42%) | catalogued as COSV60394218; called by muse, mutect2, varscan2
- SPAG17 | c.1854G>A p.L618= | Silent (SNP) | VAF 18/384 reads (5%) | catalogued as rs776481536, COSV60469171; called by muse, mutect2
